Gene-level copy-number profile of tumor specimen AP-2E8Q-QW from APOLLO case AP-2E8Q, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-2E8Q-QW: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ca55a689-ac49-4e49-a0d0-0ce27065572c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-2E8Q-DR (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/1300f36f-b7b8-4e20-83a7-4f3bf24aa467

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 2,076; copy number 2: 8,387; copy number 3: 23,106; copy number 4: 18,345; copy number 5: 4,258; copy number 6: 1,210; copy number 7: 216; copy number 8: 24; copy number 9: 1; copy number 10: 64; copy number 11: 429; copy number 12: 55; copy number 13: 106.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,087,396–12,177,550, 9 genes (within-gene range 0–2): RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr15:20,228,620–20,775,998, 20 genes: RHPN2P1, CHEK2P2, AC026495.1, HERC2P3, AC023310.1, GOLGA6L6, AC023310.3, GOLGA8CP, RN7SL759P, SPATA31E2P, AC023310.2, IGHV1OR15-6, AC023310.4, NBEAP1, AC131280.1, AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3.
- chr15:21,010,494–21,752,710, 46 genes: IGHD5OR15-5B, IGHD4OR15-4B, IGHD3OR15-3B, IGHD2OR15-2B, IGHD1OR15-1B, FAM30C, AC037471.1, BCAR1P2, RN7SL400P, AC126335.1, AC126335.2, BMS1P16, NBEAP4, AC068446.1, AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1.
- chr17:9,644,698–10,373,130, 15 genes (within-gene range 0–2): USP43, AC118755.1, AC027045.2, DHRS7C, AC027045.1, GSG1L2, AC027045.3, GLP2R, NPM1P45, RCVRN, GAS7, RPS27AP1, AC005291.2, MYH13, AC005291.1.
- chr17:10,729,777–12,143,830, 25 genes (within-gene range 0–2): TMEM220-AS1, AC015908.7, AC015908.3, AC015908.1, AC015908.4, AC015908.6, TMEM238L, AC015908.5, PIRT, AC015908.2, RNU6-1065P, RPL15P21, RN7SL601P, AC005548.1, SHISA6, AC005725.1, DNAH9, AC005209.1, AC005410.2, ZNF18, AC005410.1, MAP2K4, RNU11-2P, MIR744, AC005244.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 895 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,690,047–246,691,821, 1 gene, copy number 7: AL591848.1.
- chr5:58,198–45,895,970, 678 genes, copy number 8–13 (broad region; genes not listed).
- chr5:58,161,197–58,161,752, 1 gene, copy number 9: PGAM1P1.
- chr7:6,374,527–13,751,920, 99 genes, copy number 7 (broad region; genes not listed).
- chr7:14,145,049–14,974,777, 1 gene, copy number 7 (within-gene range 6–7): DGKB.
- chr7:14,814,131–23,208,045, 108 genes, copy number 7 (broad region; genes not listed).
- chr17:59,565,558–59,842,255, 7 genes, copy number 7: DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21.

Autosomal genes at a single copy (total copy number 1): 105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
